Gene-level copy-number profile of tumor specimen TCGA-XF-A9SG-01A from TCGA case TCGA-XF-A9SG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 81.7 years (29,825 days).
Specimen TCGA-XF-A9SG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.cd1e5b56-4216-44d6-9f67-805ff88c2155.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9SG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bcc92e6c-d514-499a-af69-9e994d5b1794

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 109; copy number 2: 21,702; copy number 3: 15,993; copy number 4: 15,540; copy number 5: 3,512; copy number 6: 2,145; copy number 7: 500; copy number 8: 80; copy number 11: 50; copy number 12: 33; copy number 13: 1; copy number 14: 8; copy number 15: 4; copy number 16: 19; copy number 18: 34; copy number 19: 36; copy number 22: 2; copy number 23: 20; copy number 26: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9SG-01A-12D-A42D-01): tumor purity 0.5, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,460 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,719,471–152,196,699, 280 genes, copy number 6 (broad region; genes not listed).
- chr1:152,205,858–152,224,193, 2 genes, copy number 6: AL589986.2, HRNR.
- chr3:11,745–96,619,831, 1,407 genes, copy number 5–18 (broad region; genes not listed).
- chr3:148,028,046–158,106,420, 198 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:160,225,496–160,755,142, 17 genes, copy number 5: C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1.
- chr3:169,083,499–174,378,005, 89 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 5: RN7SKP40.
- chr5:58,198–27,496,994, 427 genes, copy number 5 (broad region; genes not listed).
- chr5:34,651,457–37,377,971, 53 genes, copy number 12–19: AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1.
- chr5:41,951,313–45,895,970, 65 genes, copy number 6–8 (broad region; genes not listed).
- chr6:20,212,087–21,602,383, 21 genes, copy number 26 (within-gene range 2–26): AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:21,822,536–21,822,737, 1 gene, copy number 26: AL136313.1.
- chr6:47,477,789–47,627,263, 1 gene, copy number 11 (within-gene range 2–11): CD2AP.
- chr6:47,562,622–53,665,756, 111 genes, copy number 6–11 (broad region; genes not listed).
- chr8:36,378,069–37,899,497, 29 genes, copy number 6–23 (within-gene range 3–23): AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6 (broad region; genes not listed).
- chr9:14,475–1,333,953, 30 genes, copy number 5: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279.
- chr10:44,712–18,543,557, 316 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr10:35,896,874–36,435,174, 4 genes, copy number 6: LINC02630, AL355300.1, MTND5P17, MTND4P18.
- chr10:38,783,004–48,656,265, 184 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr10:73,769,264–79,445,624, 98 genes, copy number 8–22 (broad region; genes not listed).
- chr14:84,739,942–84,740,052, 1 gene, copy number 13: RNU6-976P.
- chr16:46,469,341–90,222,851, 1,141 genes, copy number 5 (broad region; genes not listed).
- chr18:47,390–9,285,985, 182 genes, copy number 5–12 (broad region; genes not listed).
- chr20:53,255,979–55,075,140, 22 genes, copy number 6 (within-gene range 3–6): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4.
- chr22:20,889,206–22,215,270, 105 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr22:29,191,697–32,205,001, 141 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 109. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
